Somatic mutation profile of tumor specimen TCGA-AA-3862-01A (aliquot TCGA-AA-3862-01A-01W-0995-10) from TCGA case TCGA-AA-3862, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 82.6 years (30,163 days).
Specimen TCGA-AA-3862-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f48f1ea-cba2-462e-a59a-d71a5a38b441.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3862-10A (Blood Derived Normal), aliquot TCGA-AA-3862-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37fe95ce-e867-48a8-8286-682f0d8ced14

The open-access MAF lists 96 somatic variants for this specimen: 74 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 68, Silent 22, Nonsense Mutation 3, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 32/121 reads (26%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 31/154 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1611C>G p.D537E | Missense Mutation (SNP) | VAF 53/110 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61684926, COSV61687202; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 53/88 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 61/100 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGER | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as rs777428643, COSV100904949; called by muse, mutect2, varscan2
- APC | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 37/170 reads (22%) | catalogued as rs1321583762, CD084022, CD941590, CM920052, COSV57321386, COSV57334587, COSV99971982; called by muse, mutect2, varscan2
- ASAH2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 158/381 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.151); catalogued as rs1265280264, COSV61483535; called by muse, mutect2, varscan2
- BAP1 | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs770654975, COSV56234783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALD1 | c.1723A>T p.R575* (on ENST00000361675 / NM_033138.4; = p.R320* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100724054; called by muse, mutect2, varscan2
- CARMIL1 | c.2792C>A p.P931H | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277101; called by muse, mutect2, varscan2
- CCDC80 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs771380755, COSV52814709; called by muse, mutect2, varscan2
- CCN3 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99422769; called by muse, mutect2, varscan2
- CFAP20DC | c.1088G>T p.R363I (on ENST00000482387 / NM_001351530.2; = p.R238I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV99918200; called by muse, mutect2, varscan2
- CFAP58 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs201674161, COSV57211922, COSV57212771; called by muse, mutect2, varscan2
- CNTN1 | c.1379+2T>G p.X460_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as rs907377175; called by muse, mutect2, varscan2
- COL4A5 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.164); catalogued as COSV100086756, COSV60373166; called by muse, mutect2, varscan2
- CREB5 | c.1255-1G>C p.X419_splice (on ENST00000357727 / NM_182898.4; = p.X412_splice on NM_004904.3) | Splice Site (SNP) | VAF 14/186 reads (8%) | catalogued as COSV100744261; called by muse, mutect2
- CTNNB1 | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62689388, COSV62713428; called by muse, mutect2, varscan2
- DCLK2 | c.596T>G p.V199G | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99651518; called by muse, mutect2, varscan2
- DDX54 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV100013633; called by muse, mutect2, varscan2
- DOCK6 | c.5810C>G p.S1937C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.139); catalogued as COSV99624950; called by muse, mutect2, varscan2
- DYNC2H1 | c.10945C>T p.R3649C | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.849); catalogued as rs763800155, COSV62098385; called by muse, mutect2, varscan2
- EBF1 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as COSV58194748; called by muse, mutect2
- ERC2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs769666433, COSV55612643; called by muse, mutect2, varscan2
- FAM78B | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 141/210 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747327778, COSV57980401; called by muse, mutect2, varscan2
- FBXL17 | c.1479A>C p.Q493H | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100670676; called by muse, mutect2, varscan2
- FER1L6 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101205532; called by muse, mutect2, varscan2
- GABRB2 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as COSV99195707; called by muse, mutect2, varscan2
- GABRR3 | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV101512264; called by muse, mutect2, varscan2
- GALK2 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375693032; called by muse, mutect2, varscan2
- GLIS3 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.295); catalogued as COSV101126926; called by muse, mutect2
- GRM8 | c.1970T>G p.L657R | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100281188; called by muse, mutect2, varscan2
- HAVCR1 | c.844T>G p.F282V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100208018; called by muse, mutect2, varscan2
- HK2 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187569366, COSV99308684; called by muse, mutect2, varscan2
- HOGA1 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs745919223, COSV101035510; ClinVar: uncertain significance; called by muse, varscan2
- IFIT5 | c.1206A>C p.E402D | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100877922; called by muse, mutect2, varscan2
- IL12RB2 | c.1072C>A p.L358I | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1409421640, COSV52021410; called by muse, mutect2, varscan2
- ITGAD | c.3077G>A p.R1026H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs761110779, COSV99791266; called by muse, varscan2
- LRRIQ3 | c.1331C>G p.A444G | Missense Mutation (SNP) | VAF 261/528 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100598522; called by muse, mutect2, varscan2
- MAP2 | c.2339C>T p.T780I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99558284; called by muse, mutect2, varscan2
- METTL14 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.039); catalogued as COSV101183369; called by muse, mutect2, varscan2
- MGST1 | c.35T>A p.V12E | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV99163158; called by muse, mutect2, varscan2
- MTRF1L | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV100922442; called by muse, mutect2
- MYCBP | c.135G>A p.L45= | Splice Region (SNP) | VAF 122/245 reads (50%) | catalogued as COSV101288919; called by muse, mutect2, varscan2
- NELL2 | c.372A>C p.E124D | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100418912; called by muse, mutect2, varscan2
- NMNAT2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs762590558, COSV54268434; called by muse, mutect2, varscan2
- NRAP | c.3137A>T p.D1046V (on ENST00000359988 / NM_001322945.2; = p.D1011V on NM_006175.4) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234291004, COSV100748306; called by muse, mutect2, varscan2
- NRXN1 | c.3814T>C p.Y1272H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100639930; called by muse, mutect2, varscan2
- NTRK2 | c.2240T>G p.F747C (on ENST00000323115 / NM_001369534.1; = p.F763C on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99453113; called by muse, mutect2, varscan2
- OR13C8 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100622939; called by muse, mutect2, varscan2
- OR4S2 | c.873A>C p.E291D | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100412572; called by muse, mutect2, varscan2
- OR5AR1 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100265584; called by muse, mutect2, varscan2
- PZP | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54353742; called by muse, varscan2
- QPRT | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54880551; called by muse, mutect2, varscan2
- RALGAPB | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.931); catalogued as rs773191841, COSV99484825; called by muse, mutect2, varscan2
- RGL3 | c.1401G>C p.R467S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.596); catalogued as COSV100992858; called by muse, mutect2
- SLC12A1 | c.85A>G p.N29D | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV100372224; called by muse, mutect2, varscan2
- SLC34A1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as rs916622007, COSV60996288; called by muse, mutect2, varscan2
- SMARCC2 | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV99910926; called by muse, mutect2, varscan2
- SNAP91 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52118089, COSV99534313, COSV99534578; called by muse, mutect2, varscan2
- SPANXD | c.174C>A p.N58K | Missense Mutation (SNP) | VAF 594/840 reads (71%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as COSV100982249; called by muse, mutect2, varscan2
- SPHKAP | c.4349G>T p.S1450I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as rs771129092, COSV100763767; called by muse, mutect2, varscan2
- SRSF7 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.885); catalogued as rs375213460; called by muse, mutect2, varscan2
- SYNE1 | c.16496A>G p.K5499R (on ENST00000367255 / NM_182961.4; = p.K5428R on NM_033071.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV54936582, COSV54962906, COSV99555537; called by muse, mutect2, varscan2
- TMPRSS11A | c.744A>T p.K248N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV100602575; called by muse, mutect2, varscan2
- TNC | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373595456, COSV100405101; called by muse, varscan2
- TTN | c.56006G>A p.R18669H (on ENST00000591111; = p.R11245H on NM_003319.4) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs569630571, COSV60169129; called by muse, mutect2, varscan2
- ZFHX4 | c.1093A>C p.S365R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV99257764; called by muse, mutect2, varscan2
- ZNF208 | c.561C>G p.H187Q | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.273); catalogued as COSV101236876, COSV101236990; called by muse, mutect2, varscan2
- ZNF479 | c.380A>T p.K127I | Missense Mutation (SNP) | VAF 149/538 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); catalogued as COSV100482561; called by muse, mutect2, varscan2
- ZSCAN16 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs199749782, COSV100481457; called by muse, mutect2, varscan2
- CTU2 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- XAGE2 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 266/857 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADPRH | c.522G>A p.A174= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs762437182, COSV100813276; called by muse, mutect2, varscan2
- C2CD2 | c.1770C>A p.A590= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100298023; called by muse, mutect2, varscan2
- FERD3L | c.165G>A p.A55= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs1237354403, COSV51762005; called by muse, mutect2, varscan2
- GABRA1 | c.1023T>G p.G341= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV50098862; called by muse, mutect2, varscan2
- HELZ | c.4383C>T p.G1461= | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as COSV100698543; called by muse, mutect2, varscan2
- HIGD1C | c.222G>A p.V74= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV101268742; called by muse, mutect2
- HYDIN | c.4821C>T p.G1607= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs1312779449, COSV59249441; called by muse, mutect2, varscan2
- IL18RAP | c.36T>C p.V12= | Silent (SNP) | VAF 41/310 reads (13%) | catalogued as COSV99961785; called by muse, mutect2, varscan2
- KCNJ3 | c.762T>G p.G254= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as COSV54532586, COSV99715366; called by muse, mutect2, varscan2
- KIAA1549 | c.2508G>A p.T836= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs746464843, COSV99649979; called by muse, mutect2, varscan2
- LILRA4 | c.612C>T p.Y204= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs149766788, COSV52491834; called by muse, mutect2, varscan2
- PAQR9 | c.951C>T p.F317= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100503703; called by muse, mutect2, varscan2
- PCDHA4 | c.267G>C p.R89= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100793204, COSV100793584, COSV63543790; called by muse, mutect2, varscan2
- RGS4 | c.234T>G p.A78= | Silent (SNP) | VAF 46/232 reads (20%) | catalogued as COSV100905521; called by muse, mutect2, varscan2
- SCN5A | c.1227G>A p.L409= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1301031890, COSV100346812; called by muse, mutect2
- SH2D4B | c.393G>A p.L131= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100213600; called by muse, mutect2, varscan2
- TEK | c.405G>A p.K135= | Silent (SNP) | VAF 48/228 reads (21%) | catalogued as COSV101193212; called by muse, mutect2, varscan2
- TMEM132D | c.1134C>T p.Y378= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1310973853, COSV70603145, COSV70617337; called by muse, mutect2, varscan2
- TRRAP | c.6532C>T p.L2178= (on ENST00000359863 / NM_001244580.1; = p.L2160= on NM_003496.3) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100722099; called by muse, mutect2, varscan2
- TTN | c.91503T>G p.V30501= (on ENST00000591111; = p.V23077= on NM_003319.4) | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100598020; called by muse, mutect2
- TULP1 | c.339C>T p.D113= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1174337620, COSV57693836; called by muse, mutect2, varscan2
- ZNF565 | c.447C>T p.D149= (on ENST00000355114; = p.D109= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as COSV100411804; called by muse, mutect2, varscan2
